Gene-level copy-number profile of tumor specimen TCGA-AO-A0JM-01A from TCGA case TCGA-AO-A0JM, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIB; Age at diagnosis: 40.1 years (14,653 days).
Specimen TCGA-AO-A0JM-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BRCA.34401e18-8273-4fbb-bbf6-4830e1d7cc96.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AO-A0JM-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 806 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/13a599a3-e770-45df-90ec-41075ef75a63

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 40; copy number 1: 384; copy number 2: 10,278; copy number 3: 26,204; copy number 4: 15,209; copy number 5: 3,985; copy number 6: 2,680; copy number 7: 123; copy number 8: 53; copy number 9: 27; copy number 10: 69; copy number 11: 43; copy number 13: 41; copy number 14: 325; copy number 15: 222; copy number 16: 14; copy number 17: 7; copy number 18: 13; copy number 19: 1; copy number 21: 20; copy number 23: 44; copy number 26: 10; copy number 33: 25.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-AO-A0JM-01A-21D-A059-01): tumor purity 0.55, ploidy 3.43, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 40 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:13,696,070–13,825,079, 2 genes: AL359771.2, PRDM2.
- chr13:18,467,172–19,344,973, 38 genes (within-gene range 0–2): ZNF962P, BNIP3P7, LINC00349, LONRF2P2, LINC00388, FEM1AP4, LINC00387, TERF1P5, FAM207BP, GXYLT1P1, CNN2P12, ZNF965P, CYP4F34P, SNX18P26, LINC00328-2P, ANKRD20A9P, RHOT1P3, RNU6-55P, RNU6-76P, SNX19P2, LINC00408, AL355516.1, PHF2P2, LINC00442, USP24P1, GTF2IP3, AL137001.1, AL137001.2, RNA5SP24, CENPIP1, AL139327.2, SMPD4P2, AL139327.3, TUBA3C, AL139327.1, PSPC1P1, ANKRD26P3, MRPL3P1.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,037 genes in 23 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:16,549,459–17,800,242, 10 genes, copy number 7 (within-gene range 5–7): CYRIA, AC008164.1, AC008069.1, LINC01866, RN7SKP168, ZFYVE9P2, PSMC1P10, RAD51AP2, VSNL1, SMC6.
- chr3:79,957,566–79,958,142, 1 gene, copy number 19: HMGB1P38.
- chr3:84,638,405–87,631,619, 24 genes, copy number 16–26: LINC00971, AC117482.1, LINC02025, AC132660.2, CADM2, MIR5688, CADM2-AS2, CADM2-AS1, THAP12P2, AC107024.1, RNU6-1129P, AC108733.1, RN7SKP284, LINC02070, AC108706.1, VGLL3, PPATP1, LINC00506, MIR4795, CHMP2B, POU1F1, KRT8P25, APOOP2, PSMC1P6.
- chr3:169,613,510–170,085,392, 24 genes, copy number 9 (within-gene range 5–9): AC007849.1, SDHDP3, RNU6-637P, TERC, Telomerase-vert, ACTRT3, AC078802.1, MYNN, AC078795.1, LRRC34, AC078795.3, AC078795.2, LRRIQ4, LRRC31, KRT18P43, SAMD7, AC008040.2, AC008040.1, AC008040.3, SEC62, SEC62-AS1, GPR160, RNU4-38P, KMT5AP3.
- chr3:170,222,424–171,054,973, 21 genes, copy number 7 (within-gene range 5–7): PRKCI, Y_RNA, AC073288.1, SKIL, AC073288.2, CLDN11, AC026316.4, MIR6828, SLC7A14-AS1, SLC7A14, KRT8P13, AC026316.1, AC026316.3, AC026316.5, AC026316.2, RPL22L1, EIF5A2, AC061708.1, KLF7P1, RNU1-70P, SLC2A2.
- chr3:171,106,664–171,106,759, 1 gene, copy number 7: MIR569.
- chr3:174,377,244–176,114,537, 19 genes, copy number 7–17: AC069218.1, NAALADL2, RN7SKP40, EEF1B2P8, NAALADL2-AS3, NAALADL2-AS2, MIR4789, RNU6-1233P, AC008180.3, RNU4-91P, AC119744.1, UBE2V1P2, RNU6-1317P, NAALADL2-AS1, AC104640.1, ACTG1P23, EI24P1, AC104640.2, AC117434.1.
- chr3:179,588,285–179,789,401, 5 genes, copy number 7: MRPL47, NDUFB5, AC090425.1, H3P13, USP13.
- chr3:179,804,063–179,804,366, 1 gene, copy number 7: AC007687.1.
- chr3:182,793,503–183,463,201, 17 genes, copy number 8 (within-gene range 4–8): ATP11B, AC069431.2, AC092953.2, DCUN1D1, AC092953.1, MCCC1, MCCC1-AS1, LAMP3, MCF2L2, B3GNT5, RNA5SP151, LINC00888, SNORA63D, AC092960.2, SNORA63E, AC092960.1, AC092960.3.
- chr3:183,697,797–185,281,990, 57 genes, copy number 7–11 (within-gene range 5–11): YEATS2, YEATS2-AS1, AC131160.1, MAP6D1, PARL, RPSAP31, MIR4448, CYP2AB1P, ABCC5, ABCC5-AS1, EEF1A1P8, HTR3D, HTR3C, HTR3C2P, Y_RNA, HTR3E-AS1, HTR3E, HSP90AA5P, AC131235.3, AC131235.2, EIF2B5, AC131235.1, DVL3, AP2M1, ABCF3, VWA5B2, MIR1224, ALG3, EEF1AKMT4, EEF1AKMT4-ECE2, CAMK2N2, ECE2, PSMD2, EIF4G1, SNORD66, FAM131A, CLCN2, POLR2H, THPO, CHRD, LINC02054, AC128714.2, LINC01839, LINC01840, EPHB3, MAGEF1, AC107294.2, LINC02069, AC107294.3, AC107294.1, AC107294.4, VPS8, C3orf70, EHHADH-AS1, EHHADH, EIF2S2P2, MIR5588.
- chr3:187,217,282–190,412,138, 36 genes, copy number 8–11 (within-gene range 6–11): MASP1, AC007920.2, RTP4, AC068299.2, AC068299.1, LINC02041, SST, RTP2, AC072022.1, BCL6, AC072022.2, AC108681.1, AC068295.1, LINC01991, AC092941.1, AC092941.2, AC022498.1, LPP-AS2, LPP, FLJ42393, LPP-AS1, MIR28, TPRG1-AS1, TPRG1, AC009319.1, TPRG1-AS2, TP63, AC078809.1, MIR944, P3H2, MTAPP2, P3H2-AS1, RNU6-1109P, NMNAT1P3, CLDN1, CLDN16.
- chr3:191,329,085–191,641,237, 4 genes, copy number 7: CCDC50, AC073365.1, PYDC2, Y_RNA.
- chr8:35,235,475–35,796,550, 1 gene, copy number 7 (within-gene range 2–7): UNC5D.
- chr8:35,525,176–36,779,209, 13 genes, copy number 7 (within-gene range 4–7): LSM12P1, AC105230.1, AC124290.1, AC124290.2, AC124290.3, MTCYBP19, MTND6P19, MTND5P41, AP006245.1, RNU6-533P, AP006245.2, AC090809.1, RPL23P10.
- chr8:57,289,552–59,893,942, 35 genes, copy number 7: RNU6-596P, AC068075.1, RPL30P10, AC068075.2, AC090796.1, AC104051.1, AC104051.2, LINC01602, AC012103.1, FAM110B, AC104350.1, AC027698.1, RPL26P26, AC092819.3, AC092819.1, AC092819.2, UBXN2B, AC009927.1, CYP7A1, PPIAP85, SDCBP, NSMAF, AC068522.1, TOX, RNU4-50P, AC105150.1, AC090152.1, AC087698.1, RNA5SP267, AC087664.3, AC087664.1, AC087664.2, AC107934.1, AC107934.2, AC022709.1.
- chr17:38,530,031–41,309,253, 167 genes, copy number 10–33 (broad region; genes not listed).
- chr17:49,202,791–52,160,017, 111 genes, copy number 14 (within-gene range 5–14) (broad region; genes not listed).
- chr17:52,862,121–53,106,358, 3 genes, copy number 8: LINC02089, LINC02876, MTCO1P40.
- chr17:53,353,427–53,439,721, 3 genes, copy number 8: AC005341.1, AC090079.1, AC090079.2.
- chr17:55,719,627–55,872,939, 3 genes, copy number 9: TMEM100, PCTP, AC090618.1.
- chr17:56,888,880–68,601,367, 378 genes, copy number 10–15 (within-gene range 6–15) (broad region; genes not listed).
- chr17:73,334,384–75,896,951, 103 genes, copy number 15 (within-gene range 3–15) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 384. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
